Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4H5, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4H5-01A (Primary Tumor).

Stomach, total gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(+)/Muc6(+)/CD10(+ +)/cERB2(-),GI(I) type)

1. Location : upper third, Center at fundus and posterior wall
2. Gross type : Borrmann type 1 (fungating)
3. Histologic type : papillary adenocarcinoma (pap)
4. Histologic type by Lauren : intestinal
5. Growth pattern: mixed expanding and infiltrative growth pattern
6. Size : 6.5x5.0cm
7. Depth of invasion : invades proper muscle (pT2)
8. Resection margins and anvil ring : free from carcinoma
safety margins: distal 21.0cm, proximal 4.5cm
9. Lymph node metastasis : no metastasis in 73 regional lymph nodes (pN0)
(lesser curvature 0/32, greater curvature 0/37, #14v 0/0, LN 0/4)
10. Lymphatic invasion : not identified
11. Venous invasion : not identified
12. Perineural invasion : not identified
13. Associated finding: peritumoral lymphocytic infiltration, moderate
14. Other finding: jejunum - no tumor.
- # Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

ICD-O-3

adenocarcinoma, papillary, NOS 8260/3

Site: Stomach, fundus C16.1

hw 9/27/12

hw 9/27/12

Source: NCI Genomic Data Commons file 543a1134-1957-4b9b-bcda-d665c5fe4d55 (TCGA-HU-A4H5.FAA7C711-71B3-47A5-95C1-2A8005E6AA76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).